Gene-level copy-number profile of tumor specimen TCGA-B6-A0I2-01A from TCGA case TCGA-B6-A0I2, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 45.7 years (16,702 days).
Specimen TCGA-B6-A0I2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.aa5e3733-d47a-4371-99ab-34d98aec9bf6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0I2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c0e25cb-e601-447e-a43e-5529813a36b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,174; copy number 2: 30,501; copy number 3: 5,219; copy number 4: 16,604; copy number 5: 2,951; copy number 6: 2,146; copy number 7: 437; copy number 8: 649; copy number 9: 3; copy number 10: 57; copy number 11: 60; copy number 13: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0I2-01A-11D-A036-01): tumor purity 0.46, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,310 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,350,934–39,487,177, 64 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–4,883,716, 97 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:125,348,196–145,066,685, 364 genes, copy number 6–9 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 6 (broad region; genes not listed).
- chr11:14,262,846–49,208,638, 569 genes, copy number 6–13 (broad region; genes not listed).
- chr11:66,409,158–83,423,516, 495 genes, copy number 6–10 (broad region; genes not listed).
- chr11:86,945,679–91,993,255, 113 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 6–8 (broad region; genes not listed).
- chr19:39,083,913–45,602,212, 347 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:50,343,304–50,801,309, 31 genes, copy number 8 (within-gene range 4–8): PPP6R2, SBF1, ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, AC000050.2, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 1,174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
